Somatic mutation profile of tumor specimen TCGA-55-8097-01A (aliquot TCGA-55-8097-01A-11D-2238-08) from TCGA case TCGA-55-8097, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,260 days).
Specimen TCGA-55-8097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27f13a1b-7d09-476f-830b-69385d58630c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8097-10A (Blood Derived Normal), aliquot TCGA-55-8097-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/253c1afc-931d-412c-8f2b-d1f9e466e6ed

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Nonsense Mutation 3, Frame Shift Del 3, Intron 3, Splice Site 2, Frame Shift Ins 1, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.2660C>A p.T887N | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278667394, COSV100217890; called by muse, mutect2, varscan2
- ANKRD53 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs782121746, COSV99721635; called by muse, mutect2, varscan2
- ANTXR2 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs529468896, COSV99786611; called by muse, mutect2, varscan2
- ARID1A | c.2512G>T p.G838* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as COSV61373162; called by muse, mutect2, varscan2
- BCHE | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100012603, COSV100013122; called by muse, mutect2, varscan2
- BICC1 | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.986); catalogued as COSV99571037; called by muse, mutect2
- CALCR | c.1077G>T p.K359N (on ENST00000649521 / NM_001164737.2; = p.K343N on NM_001742.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100810710; called by muse, mutect2, varscan2
- CD109 | c.2049T>G p.S683R | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99755046; called by muse, mutect2, varscan2
- CDC42BPB | c.3248A>G p.K1083R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV100775727; called by muse, mutect2, varscan2
- CLCN5 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs1557194541, COSV100260051, COSV56583520; called by muse, mutect2, varscan2
- COL1A2 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.266); catalogued as COSV99801596; called by muse, mutect2, varscan2
- CORIN | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV99904712; called by muse, mutect2
- CUL4B | c.314T>A p.V105D | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV100341348; called by muse, mutect2
- CYP26C1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV99592695; called by muse, mutect2
- EPRS1 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859558, COSV65097113; called by muse, mutect2, varscan2
- ESM1 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1462157150, COSV101195732; called by muse, mutect2, varscan2
- EZHIP | c.229A>C p.I77L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1557318632, COSV100539973; called by muse, mutect2, varscan2
- FCRLB | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs780046443, COSV100396465; called by muse, mutect2, varscan2
- FNDC1 | c.3001G>T p.A1001S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99797458; called by muse, mutect2, varscan2
- FREM1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763640629, COSV101085289; called by muse, mutect2, varscan2
- GBF1 | c.1150G>A p.V384M (on ENST00000369983 / NM_001377137.1; = p.V383M on NM_004193.3) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375568604; called by muse, mutect2, varscan2
- H3C6 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs777435873, COSV100839043; called by muse, mutect2, varscan2
- HAVCR2 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100325064; called by muse, mutect2, varscan2
- HERC2 | c.3130A>T p.S1044C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV99877753; called by muse, mutect2
- IFNA2 | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101207001; called by muse, mutect2, varscan2
- INTS5 | c.1453T>G p.C485G | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100399884; called by muse, mutect2, varscan2
- IRS4 | c.3652C>G p.R1218G | Missense Mutation (SNP) | VAF 60/471 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs779993930, COSV100929855; called by muse, mutect2, varscan2
- IST1 | c.809A>G p.N270S (on ENST00000535424 / NM_001270976.1; = p.N257S on NM_014761.4) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs201876449; called by muse, mutect2
- LAMA2 | c.867C>A p.C289* | Nonsense Mutation (SNP) | VAF 105/255 reads (41%) | catalogued as COSV101370966; called by muse, mutect2, varscan2
- LARP1B | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99219128; called by muse, mutect2, varscan2
- LRP1B | c.11095T>A p.C3699S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101262206; called by muse, varscan2
- MAPK9 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs746133033, COSV100558221, COSV100558759; called by muse, mutect2, varscan2
- MCM3AP | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV99387658; called by muse, mutect2, varscan2
- MGAT3 | c.1424C>G p.A475G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV100362120; called by muse, mutect2
- MPPED1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV68837356; called by muse, mutect2, varscan2
- MROH2B | c.4652G>T p.R1551L | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV101270979, COSV68190041; called by muse, mutect2, varscan2
- MYH7 | c.5283+1G>A p.X1761_splice | Splice Site (SNP) | VAF 19/332 reads (6%) | catalogued as rs775803553, CS115880, COSV62520615; called by muse, mutect2
- NAA15 | c.2302+2T>A p.X768_splice | Splice Site (SNP) | VAF 10/123 reads (8%) | catalogued as COSV99650033; called by muse, mutect2
- NIN | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99815868; called by muse, mutect2, varscan2
- NPC2 | c.334_335insCC p.K112Tfs*5 | Frame Shift Ins (INS) | VAF 79/263 reads (30%) | catalogued as COSV99467412; called by mutect2, pindel, varscan2
- NRG3 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932801, COSV64574651; called by muse, mutect2
- OGT | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV101035690; called by muse, mutect2
- OR2L2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs914168723, COSV63552073; called by muse, mutect2, varscan2
- PAK3 | c.1352G>A p.R451Q (on ENST00000262836 / NM_001324328.2; = p.R436Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53277405, COSV99458618; called by muse, mutect2, varscan2
- PARD6A | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99538069; called by muse, mutect2, varscan2
- PCDHAC2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1554228854, COSV99145613, COSV99152764; called by muse, mutect2
- PFAS | c.1373G>T p.R458M | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58979501; called by muse, mutect2, varscan2
- PGK1 | c.639C>A p.G213= | Splice Region (SNP) | VAF 43/177 reads (24%) | catalogued as CD004811, CS075201, COSV100965386, COSV64832752; called by muse, mutect2, varscan2
- POLA1 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.499); catalogued as COSV100985882; called by muse, mutect2, varscan2
- PPP2R3B | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1216420604, COSV101180860; called by muse, mutect2, varscan2
- PRDM9 | c.1119G>T p.W373C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV57010649, COSV99691556; called by muse, mutect2, varscan2
- PRKN | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs1233588284, COSV100632105, COSV58231609; called by muse, mutect2, varscan2
- PRRX1 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV53413046, COSV99510567; called by muse, mutect2, varscan2
- PXDNL | c.4181G>T p.G1394V | Missense Mutation (SNP) | VAF 45/442 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV100687304, COSV62488818; called by muse, mutect2, varscan2
- RFC1 | c.989A>C p.Y330S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100568134; called by muse, mutect2
- ROBO2 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59914086, COSV59919821; called by muse, mutect2, varscan2
- SACS | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV101207867; called by muse, mutect2, varscan2
- SCN10A | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1294999278, COSV71861574; called by muse, mutect2, varscan2
- SDK1 | c.4184G>A p.R1395Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141481774; called by muse, mutect2, varscan2
- SPRY3 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.584); catalogued as COSV100249653; called by muse, mutect2
- SPTBN5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs371286100; called by muse, mutect2, varscan2
- SRL | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.439); catalogued as COSV101281376; called by muse, mutect2, varscan2
- SUSD3 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100968932; called by muse, mutect2, varscan2
- SYK | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs796052158, COSV65328894; called by muse, mutect2, varscan2
- SYT4 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54901075, COSV99674625; called by muse, mutect2, varscan2
- TBPL2 | c.1117A>T p.K373* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs767811298, COSV55955610; called by muse, mutect2, varscan2
- TCEAL1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1052146, COSV101010139; called by muse, mutect2, varscan2
- TFPI | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99260035; called by muse, mutect2, varscan2
- TIMM50 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as rs753312005, COSV100068146; called by muse, mutect2, varscan2
- TMEFF1 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as COSV100615140; called by muse, mutect2, varscan2
- TMEM132E | c.794C>T p.T265I (on ENST00000321639; = p.T355I on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV100396917; called by muse, mutect2, varscan2
- TMEM200A | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV51650184, COSV99760337; called by muse, mutect2
- TPP2 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV101060520; called by muse, mutect2, varscan2
- TRPC6 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV100723812; called by muse, mutect2, varscan2
- TSHZ3 | c.2673G>T p.R891S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99553243; called by muse, mutect2, varscan2
- USP24 | c.5551C>A p.L1851I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99601351; called by muse, mutect2, varscan2
- UTRN | c.2036A>G p.K679R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV100840790; called by muse, mutect2, varscan2
- VCAN | c.5696T>C p.I1899T | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99427871; called by muse, mutect2, varscan2
- VPS13A | c.5600C>G p.S1867C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100653916, COSV62438872; called by muse, mutect2, varscan2
- WDR49 | c.1180T>C p.S394P (on ENST00000308378 / NM_001366158.1; = p.S735P on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100394108; called by muse, mutect2, varscan2
- ZNF626 | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371677016; called by muse, mutect2, varscan2
- ZNF672 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.893); catalogued as rs766659773, COSV100129424, COSV100129481; called by muse, mutect2, varscan2
- C2CD2L | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DOCK4 | c.4501del p.L1501* | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- SLAMF7 | c.920T>A p.V307E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- THAP5 | c.814_815del p.I272Cfs*7 (on ENST00000415914 / NM_001130475.3; = p.I230Cfs*7 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/122 reads (30%) | called by mutect2, pindel, varscan2
- TNPO1 | c.2076del p.Q693Rfs*7 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, pindel, varscan2
- ALDOA | c.717C>T p.P239= (on ENST00000642816 / NM_001243177.4; = p.P185= on NM_184041.5) | Silent (SNP) | VAF 35/208 reads (17%) | catalogued as rs1393953617, COSV100582303; called by muse, mutect2, varscan2
- CACNA1S | c.1134T>G p.V378= | Silent (SNP) | VAF 83/275 reads (30%) | catalogued as COSV100755480; called by muse, mutect2, varscan2
- EEF1A1 | c.714A>G p.P238= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as rs930158177, COSV100303504; called by muse, mutect2, varscan2
- FLT1 | c.2961C>T p.D987= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs751715034, COSV56724746; called by muse, mutect2, varscan2
- FOXJ3 | c.78T>A p.S26= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV100692405; called by muse, mutect2, varscan2
- GABRA1 | c.852C>T p.V284= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV99196390; called by muse, mutect2, varscan2
- GRIA1 | c.2259G>A p.G753= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV99603025; called by muse, mutect2, varscan2
- IGKV1D-16 | c.18C>A p.L6= | Silent (SNP) | VAF 73/316 reads (23%) | catalogued as rs758610663; called by muse, mutect2, varscan2
- KDM5C | c.4215G>A p.E1405= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV100948739, COSV100949618, COSV64762837; called by muse, mutect2, varscan2
- LDLRAD3 | c.129C>T p.I43= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as COSV100215488; called by muse, mutect2, varscan2
- LRRIQ1 | c.4260G>A p.E1420= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV67826320, COSV67841933; called by muse, mutect2, varscan2
- MYH15 | c.534C>T p.N178= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs753189702, COSV99844603; called by muse, mutect2, varscan2
- OR1B1 | c.774C>T p.Y258= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs142453546; called by muse, mutect2, varscan2
- OR6N1 | c.747C>T p.L249= | Silent (SNP) | VAF 42/304 reads (14%) | catalogued as COSV58649134; called by muse, mutect2, varscan2
- PPME1 | c.165T>C p.D55= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as rs746920933, COSV100076821; called by muse, mutect2, varscan2
- RAB3C | c.30C>A p.A10= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99279062; called by muse, mutect2, varscan2
- RYR2 | c.5115G>C p.L1705= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100773426, COSV63680243; called by muse, mutect2, varscan2
- SASH1 | c.66G>A p.E22= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100821555; called by muse, varscan2
- SLIT1 | c.1767C>A p.A589= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV99822918; called by muse, mutect2, varscan2
- SLN | c.16C>A p.R6= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV60006580; called by muse, mutect2, varscan2
- SPTA1 | c.1161C>T p.N387= | Silent (SNP) | VAF 46/332 reads (14%) | catalogued as rs773982782, COSV100935844; called by muse, varscan2
- TNXB | c.6630C>T p.V2210= (on ENST00000647633; = p.V1963= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs774343311, COSV100926798; called by muse, mutect2
- ZC3H12A | c.72C>T p.D24= | Silent (SNP) | VAF 49/178 reads (28%) | catalogued as COSV66104270; called by muse, mutect2, varscan2
- ZNF114 | c.375T>C p.D125= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100252185; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1218G>A | Intron (SNP) | VAF 15/51 reads (29%) | catalogued as rs533095580, COSV66928122; called by muse, mutect2, varscan2
- DDHD1 | c.1846+2574A>C | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100080274; called by muse, mutect2, varscan2
- EXOSC5 | c.-2C>T | 5'UTR (SNP) | VAF 79/262 reads (30%) | catalogued as COSV99524857; called by muse, mutect2, varscan2
- MARK2 | c.55-4924T>C | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SERPINA13P | n.117G>T | RNA (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
